Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A016, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A016-01A (Primary Tumor).

Diagnosis:

1. : Resected colon with a centrally ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located 1.5 cm from the aboral resection margin, extended 6 cm in length, with infiltration of the perirectal fatty tissue and four local lymph node metastases. Tumor-free colon resection margins. Tumor-free mesocolic resection margin.
2. : Tumor-free, clearly periureteral soft tissue with focal fibrosis.
3. : Appendix with signs of previous, healed, appendicitis and mild florid periappendicitis.

Stage of tumor: pT3 pN2 (4/19), pMX; G2, L1, V0, local R0.

1CD-0-3

Adenocarcinoma, NOS 8140/3

Site: rectum C20.9 for 3/31/11

Primary Discrepancy		
Case # (cycle):		
Reviewing Institute:		

Source: NCI Genomic Data Commons file 6505c3dd-7204-4294-b5fd-e1f5e7c7fd45 (TCGA-AG-A016.61E530D2-A683-4BDE-8AF0-5C99283A1E70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).